Somatic mutation profile of tumor specimen C3N-01213-01 (aliquot CPT0075720009) from CPTAC case C3N-01213, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 68.3 years (24,944 days).
Specimen C3N-01213-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 599955b1-72ea-43e3-ac4a-1eae3ad23254.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01213-71 (Blood Derived Normal), aliquot CPT0075800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95208c32-f1cb-42d6-93cb-ca55b41d43e9

The open-access MAF lists 95 somatic variants for this specimen: 64 protein-altering or splice-affecting, 22 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 22, Frame Shift Del 10, Splice Region 4, Intron 4, Splice Site 4, RNA 3, Nonstop Mutation 1, In Frame Del 1, Nonsense Mutation 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFMID | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV59977289; called by muse, mutect2, varscan2
- ALDOA | c.730G>C p.E244Q (on ENST00000642816 / NM_001243177.4; = p.E190Q on NM_184041.5) | Missense Mutation (SNP) | VAF 152/735 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57632073; called by muse, mutect2, varscan2
- ART5 | c.132G>C p.E44D | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as rs372759673; called by muse, mutect2, varscan2
- ASTN2 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); catalogued as rs1296659562, COSV57748006, COSV57776763; called by muse, mutect2, varscan2
- CFAP58 | c.2348C>T p.T783M | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs140537135; called by muse, mutect2, varscan2
- CHMP2B | c.638A>T p.D213V | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV55462889; called by muse, mutect2, varscan2
- CYP26B1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.125); catalogued as COSV50012580; called by muse, mutect2, varscan2
- DNAJC7 | c.78G>A p.R26= | Splice Region (SNP) | VAF 13/65 reads (20%) | catalogued as rs782405460; called by muse, mutect2, varscan2
- IER5 | c.955C>G p.P319A | Missense Mutation (SNP) | VAF 76/532 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.578); catalogued as COSV100849683; called by muse, mutect2, varscan2
- JAK3 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 68/370 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs746488415, COSV71686814; called by muse, mutect2, varscan2
- PDIA2 | c.516C>G p.D172E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs374019509; called by muse, mutect2, varscan2
- RYR1 | c.14468C>T p.T4823M | Missense Mutation (SNP) | VAF 62/336 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs148540135, CM083554; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCAP | c.3538G>A p.D1180N | Missense Mutation (SNP) | VAF 107/487 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1281346457; called by muse, mutect2, varscan2
- SOHLH1 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 48/325 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs146613743; called by muse, mutect2, varscan2
- ZNF536 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs1424861671; called by muse, mutect2, varscan2
- ADAMTS6 | c.1073+1G>C p.X358_splice | Splice Site (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- AL021368.4 | n.136-2A>C | Splice Site (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- AVPR1B | c.658A>G p.S220G | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BIRC6 | c.13448del p.K4483Rfs*5 | Frame Shift Del (DEL) | VAF 30/208 reads (14%) | called by pindel, varscan2
- CACNB4 | c.27C>G p.N9K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CALD1 | c.146G>C p.R49P | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC110 | c.348+1G>T p.X116_splice | Splice Site (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2
- CELF4 | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CFAP74 | c.3113T>C p.V1038A | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- CHD9 | c.752del p.N251Ifs*9 | Frame Shift Del (DEL) | VAF 28/122 reads (23%) | called by mutect2, pindel, varscan2
- CHRNB3 | c.899T>A p.L300Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHUK | c.2208+3A>G | Splice Region (SNP) | VAF 45/243 reads (19%) | called by muse, mutect2, varscan2
- DNAH2 | c.9053G>C p.R3018T | Missense Mutation (SNP) | VAF 96/500 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- DUXA | c.436del p.Q146Kfs*23 | Frame Shift Del (DEL) | VAF 11/89 reads (12%) | called by mutect2, pindel, varscan2
- EIF3L | c.1259T>C p.F420S | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELAPOR1 | c.1628A>T p.E543V | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- FIGN | c.2174C>G p.T725R | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- FRY | c.8583G>T p.L2861= | Splice Region (SNP) | VAF 64/345 reads (19%) | called by muse, varscan2
- FRYL | c.3733T>A p.L1245M | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- FUZ | c.220del p.S74Afs*20 | Frame Shift Del (DEL) | VAF 58/405 reads (14%) | called by mutect2, varscan2
- HNRNPUL2 | c.394G>C p.A132P | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IDO1 | c.1202A>T p.K401M | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- KLF15 | c.239_273del p.L80Qfs*4 | Frame Shift Del (DEL) | VAF 38/150 reads (25%) | called by mutect2, pindel
- MAX | c.458A>T p.K153M | Missense Mutation (SNP) | VAF 73/385 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MMRN1 | c.2422G>T p.G808C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- NAGPA | c.765T>G p.H255Q | Missense Mutation (SNP) | VAF 85/576 reads (15%) | PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- NOC2L | c.1535A>T p.N512I | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- NUP93 | c.1332G>C p.L444F | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PBRM1 | c.666_667del p.I223Nfs*2 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- PHIP | c.3691A>G p.I1231V | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PRRC2C | c.111A>G p.T37= | Splice Region (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- PTPRB | c.3430T>A p.L1144M | Missense Mutation (SNP) | VAF 62/382 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAD21L1 | c.1460T>G p.L487R | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- RALGAPB | c.3891del p.K1297Nfs*5 | Frame Shift Del (DEL) | VAF 21/122 reads (17%) | called by mutect2, pindel, varscan2
- RANBP6 | c.2113G>C p.V705L | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- RC3H1 | c.583del p.G196Dfs*9 | Frame Shift Del (DEL) | VAF 55/232 reads (24%) | called by mutect2, pindel, varscan2
- RELB | c.688G>C p.V230L | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- RPS6KC1 | c.1532G>A p.S511N | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- SNRNP200 | c.5488G>A p.E1830K | Missense Mutation (SNP) | VAF 98/547 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- TBL2 | c.901_902del p.G301Yfs*26 | Frame Shift Del (DEL) | VAF 30/140 reads (21%) | called by mutect2, pindel
- TENM3 | c.984T>A p.F328L | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.018); called by muse, varscan2
- TERB1 | c.1673T>C p.L558S | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TNFAIP8 | c.32-2_34delinsTTTTT p.X11_splice | Splice Site (ONP) | VAF 4/45 reads (9%) | called by pindel, varscan2*
- TNRC18 | c.7465del p.A2489Rfs*11 | Frame Shift Del (DEL) | VAF 23/200 reads (12%) | called by mutect2, pindel, varscan2
- TRERF1 | c.1956_1958del p.K653del | In Frame Del (DEL) | VAF 71/375 reads (19%) | called by mutect2, pindel, varscan2
- TSGA13 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 29/205 reads (14%) | called by muse, mutect2, varscan2
- VHL | c.640_*2del | Nonstop Mutation (DEL) | VAF 55/367 reads (15%) | called by mutect2, pindel, varscan2
- ZMYND8 | c.134A>C p.K45T (on ENST00000311275 / NM_001363741.2; = p.K65T on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/320 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF420 | c.719G>C p.R240P | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ALLC | c.372T>A p.I124= | Silent (SNP) | VAF 20/171 reads (12%) | called by muse, mutect2, varscan2
- ATR | c.6738T>C p.L2246= | Silent (SNP) | VAF 48/170 reads (28%) | called by muse, mutect2, varscan2
- CALML6 | c.261G>A p.G87= | Silent (SNP) | VAF 28/177 reads (16%) | catalogued as COSV57070873; called by muse, mutect2, varscan2
- CDC14C | c.1446C>G p.V482= (on ENST00000428251; = p.V375= on NM_152627.3) | Silent (SNP) | VAF 58/322 reads (18%) | catalogued as rs780478630; called by muse, mutect2, varscan2
- CNGA2 | c.1170T>C p.D390= | Silent (SNP) | VAF 72/156 reads (46%) | catalogued as COSV100323754; called by muse, mutect2, varscan2
- CYP4B1 | c.1473C>A p.V491= | Silent (SNP) | VAF 45/269 reads (17%) | catalogued as COSV99597292; called by muse, mutect2, varscan2
- DND1 | c.1005T>A p.S335= | Silent (SNP) | VAF 60/323 reads (19%) | called by muse, mutect2, varscan2
- FBXL16 | c.729C>T p.R243= | Silent (SNP) | VAF 6/150 reads (4%) | catalogued as rs1242654994; called by muse, mutect2
- KDM6B | c.4734C>T p.C1578= | Silent (SNP) | VAF 116/681 reads (17%) | catalogued as rs758258171, COSV54679490; called by muse, mutect2, varscan2
- MAGEL2 | c.3099C>G p.V1033= | Silent (SNP) | VAF 50/217 reads (23%) | called by muse, mutect2, varscan2
- MRPS30 | c.105C>T p.D35= | Silent (SNP) | VAF 35/267 reads (13%) | catalogued as rs1475089695; called by muse, mutect2, varscan2
- MYO9A | c.1746C>T p.I582= | Silent (SNP) | VAF 9/127 reads (7%) | catalogued as COSV61849557; called by muse, mutect2
- NLGN3 | c.2115C>T p.S705= (on ENST00000358741 / NM_181303.2; = p.S685= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/219 reads (5%) | called by muse, mutect2
- NPAS3 | c.2145C>T p.V715= (on ENST00000356141 / NM_001164749.2; = p.V683= on NM_022123.3) | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as COSV100640241; called by muse, mutect2, varscan2
- OR1M1 | c.405C>T p.I135= | Silent (SNP) | VAF 62/281 reads (22%) | catalogued as rs1274812504; called by muse, mutect2, varscan2
- RBL1 | c.2304G>C p.L768= | Silent (SNP) | VAF 27/226 reads (12%) | called by muse, mutect2, varscan2
- RELN | c.5712G>C p.T1904= | Silent (SNP) | VAF 36/226 reads (16%) | catalogued as COSV58986674, COSV59033067; called by muse, mutect2, varscan2
- SCAF4 | c.2433T>C p.P811= | Silent (SNP) | VAF 53/281 reads (19%) | called by muse, mutect2, varscan2
- SEMA7A | c.45C>T p.R15= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, varscan2
- SEPTIN14 | c.693T>C p.T231= | Silent (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- SLC35B4 | c.949C>T p.L317= | Silent (SNP) | VAF 102/304 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.13029G>A p.T4343= (on ENST00000591111; = p.T4297= on NM_003319.4) | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs1384061855; called by muse, varscan2
- AC078880.2 | n.105T>C | RNA (SNP) | VAF 19/250 reads (8%) | catalogued as rs1430145319; called by muse, mutect2
- DCHS2 | n.3006dup | RNA (INS) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- MAPK8IP1P2 | n.288G>T | RNA (SNP) | VAF 37/278 reads (13%) | catalogued as rs1173867623; called by muse, mutect2, varscan2
- MORN4 | c.-117_-108del | 5'UTR (DEL) | VAF 55/415 reads (13%) | called by mutect2, pindel, varscan2
- NFATC4 | c.1732+33C>G | Intron (SNP) | VAF 16/440 reads (4%) | catalogued as rs1234027811; called by muse, mutect2
- PLEKHA6 | c.1524+1714A>T | Intron (SNP) | VAF 42/184 reads (23%) | called by muse, mutect2, varscan2
- SCARA3 | chr8:27676583 T>A | 3'Flank (SNP) | VAF 24/124 reads (19%) | called by muse, mutect2, varscan2
- SCN1B | c.448+277G>A | Intron (SNP) | VAF 18/578 reads (3%) | called by muse, mutect2
- SORBS1 | c.2129-1237dup | Intron (INS) | VAF 57/333 reads (17%) | called by mutect2, pindel, varscan2
